Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACJ-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC with rupture

Specimen : Liver

Gross Photo : 1

GROSS:

1. Specimen:

Liver: 17.0 x 11.5 x 8.5 cm, 750.0 gm, unfixed

Gallbladder: 11.0 cm in length, 4.8 cm in diameter, 1.0 mm in thickness,
unfixed

2. Tumor location: right

Tumor number: one

Tumor size: 11.0 x 9.0 x 8.0 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: yes (10-20 %)

6. Hemorrhage/peliosis: yes (10-20 %)

7. Portal vein invasion: yes

8. Bile duct invasion: no

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
Q2 5/19/14

Gross photo present.

Blocks

TB, T1-5, tumor mass x 6

NB,A, non-tumorous tissue x 2

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

1. Hepatocellular carcinoma:

1-1. Differentiation

The worst differentiation II

The major differentiation II

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Fibrous capsule formation: partial capsule

3. Capsular infiltration: no

4. Septum formation: yes

5. Surgical resection margin invasion: no, margin of the clearance (0.5 cm)

[page 2 of 2]
6. Serosal invasion: no
7. Portal vein invasion: yes
8. Bile duct invasion: no
9. Hepatic vein invasion: no
10. Hepatic artery invasion: no
11. Microvessel invasion: yes
12. Intrahepatic metastasis: no
13. Multicentric occurrence: no

NOT reported. Gross:

NOT reported. Gross:

Urine, smear, inflammation

Urine, smear, inflammation

Urine, smear, atypical cells

Urine, smear, atypical cells

Urine, smear, inflammation

Urine, smear, inflammation

Urine, smear, inflammation

Liver, ectomy, hepatocellular carcinoma, cirrhosis, steatosis
T56000, P10, M81703, M49500, M50080
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, right lobe, lobectomy:
Hepatocellular carcinoma, well differentiated
Cirrhosis, micronodular
Steatosis, mild
Gallbladder, cholecystectomy:
Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file 5f7dbe4c-5ed4-4688-ace9-a0f17bf8f4f6 (TCGA-DD-AACJ.2CD482F0-0882-4A61-9B40-1D7B3DBC625E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).